Surgical pathology report (de-identified scan), TCGA case TCGA-3B-A9HJ, project TCGA-SARC (Sarcoma), tissue source site Moffitt Cancer Center, specimen TCGA-3B-A9HJ-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Final Diagnosis

- A. GROIN MASS, LEFT, BIOPSY:
Dedifferentiated liposarcoma (well differentiated and low grade spindle cell sarcoma with prominent myxoid and inflammatory change).
Foci of small lymphocytic lymphoma associated with the spindle cell sarcoma.
Tumor size: overall 11.6 x 10.5 x 6.5 cm with circumscribed 7.7 x 6.7 x 5.8 cm area of Non-lipogenic sarcoma
Tumor necrosis: None
Mitotic activity: No mitoses seen (less than 1% proliferative index on Ki-67)
Other findings: Benign lymph node (1),
See Comment.

COMMENT: The groin mass is composed of soft tissue and hematologic malignancies. The soft tissue tumor is a dedifferentiated liposarcoma which is composed predominantly of a non-lipogenic spindle cell sarcoma surrounded by well differentiated liposarcoma, adipocytic and focal sclerosing variants. The spindle cell sarcoma appears to be predominantly low grade with scattered moderately to rarely markedly atypical spindled and epithelioid nuclei in foci off background of myxoid stromal change. Inflammatory cells (predominantly plasma cells with a few scattered eosinophils and lymphocytes) are intermixed with the tumor. These areas are separate from the associated hematopoietic component. Immunohistochemical stains on the spindle cell sarcoma show tumor cells to be diffusely positive for vimentin and CD68, and negative for actin, desmin and CD43. Ki-67 reveals low proliferative activity with less than 1% of nuclei staining (manual estimate). Multiple foci of lymphoid aggregates with and without germinal centers are present associated only with the spindle cell sarcoma. Some of these aggregates are composed of a monotonous population of small lymphoid cells with clumped chromatin and scant cytoplasm. Immunohistochemical stains highlight these small cells showing them to be B-cells (CD20+, CD79a+) with coexpression of weak CD5 and CD23 (partial). BCL-1 is negative, excluding mantle cell lymphoma. CD3 is positive in T-cells. ISH with kappa and lambda probes demonstrate polyclonal plasma cells. The overall findings of this component are consistent with small lymphocytic lymphoma (SLL). This correlates with the concurrent flow cytometric and FISH CLL panel results (). The hematopoietic workup and diagnosis was performed in association with Dr. (Hematopathologist).

I, the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically signed out by

Specimen(s) Received

A LEFT GROIN MASS

Clinical History

ICD-O-3
Liposarcoma, dedifferentiated
885813
Site: Groin NOS
249.5
J 4/22/14

[page 2 of 2]
NOT PROVIDED.

Preoperative Diagnosis

LEFT GROIN MASS.

Intraoperative Consultation

FSA1. LEFT GROIN MASS:

Myxoid neoplasm with nodular foci of mixed lymphoid and plasmacytic cells and histiocytes (suggestive of lymph node), mesenchymal neoplasm favored.

NOTE: Frozen section tissue also seen by Dr. _____ who does not feel that this is unequivocally lymphoma. Tissue sent for flow cytometry.

I, _____ MD, have performed the intraoperative consultation and issued the above diagnosis.

Gross Description

A. The specimen is received fresh labeled "left groin mass, history of possible lymphoma" and consists of an 11.6 x 10.5 x 6.5 cm encapsulated portion of homogenous yellow, lobulated adipose tissue. No areas of hemorrhage or necrosis are identified. There is a small amount of attached skeletal muscle. The tissue is inked black. At the periphery of the mass is a 7.7 x 6.7 x 5.8 cm, well-circumscribed, firm, tan yellow, brown lobulated mass with a thin membranous lining. The cut surface is glistening. The mass is inked blue. There are additional adjacent soft tan and yellow nodules up to 4.0 cm in greatest dimension suggestive of possible lymph nodes. A representative section of the peripheral nodule is frozen and entirely submitted in FSA1. Additional representative sections are submitted as follows:

- A2-A6: Possible lipoma
- A7-A13: Peripheral nodule
- A14-A15: One nodule, bisected ? lymph node
- A16-A20: One possible lymph node, sectioned

A portion of the tissue is submitted to the

W 11/2/14

100

Source: NCI Genomic Data Commons file 3e12784b-b41e-466c-8c6c-f30318781381 (TCGA-3B-A9HJ.3A5E74EF-9BA3-4676-A8B7-77BDAD66EB5D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).